Somatic mutation profile of tumor specimen MP2PRT-PAVDLC-TMP1-A (aliquot MP2PRT-PAVDLC-TMP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVDLC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.8 years (2,854 days).
Specimen MP2PRT-PAVDLC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7ffb256-4d3a-48e2-be6f-6b11d90e29cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVDLC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVDLC-NB1-A-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50f328ad-9ab2-4bfa-906d-90f120f8b32d

The open-access MAF lists 55 somatic variants for this specimen: 31 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 23, Frame Shift Ins 2, 3'UTR 1, Frame Shift Del 1, In Frame Ins 1, Splice Site 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.1773_1793dup p.Y597_E598insDVDFREY | In Frame Ins (INS) | VAF 48/180 reads (27%) | catalogued as rs864321619, COSV54046520, COSV54071244, COSV99610659; ClinVar: pathogenic; called by mutect2, varscan2
- RUNX1 | c.922C>T p.Q308* (on ENST00000344691 / NM_001001890.3; = p.Q335* on NM_001754.5) | Nonsense Mutation (SNP) | VAF 176/866 reads (20%) | catalogued as rs1569002881, COSV55896726; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANKRD31 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as rs1485813671, COSV57158931; called by muse, mutect2, varscan2
- ANOS1 | c.1449C>T p.H483= | Splice Region (SNP) | VAF 76/82 reads (93%) | catalogued as rs147662148; called by muse, mutect2, varscan2
- ECT2 | c.2629C>T p.R877C (on ENST00000392692 / NM_001349098.2; = p.R846C on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 77/184 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); catalogued as rs1221596751, COSV99221051; called by muse, mutect2, varscan2
- FN3KRP | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 70/207 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1439981727; called by muse, mutect2, varscan2
- FPR2 | c.383T>G p.L128R | Missense Mutation (SNP) | VAF 125/264 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); catalogued as rs886383123; called by muse, mutect2, varscan2
- KRT3 | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 264/567 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV58816396; called by muse, mutect2, varscan2
- MAP3K9 | c.3245C>T p.P1082L (on ENST00000554752 / NM_001284230.1; = p.P1096L on NM_033141.4) | Missense Mutation (SNP) | VAF 124/270 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775309790, COSV67121147; called by muse, mutect2, varscan2
- NSMAF | c.1186G>A p.G396S | Missense Mutation (SNP) | VAF 52/216 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as COSV50687186; called by muse, mutect2, varscan2
- PAGE3 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 42/46 reads (91%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.818); catalogued as rs1424146198; called by muse, mutect2, varscan2
- ROBO1 | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 113/249 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); catalogued as rs1322311249, COSV71395645; called by muse, mutect2, varscan2
- SCARA5 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 231/716 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs766861715, COSV57276546; called by muse, mutect2, varscan2
- SH2B3 | c.1566dup p.E523Rfs*23 | Frame Shift Ins (INS) | VAF 256/453 reads (57%) | catalogued as rs751076276; called by pindel, varscan2
- SOX6 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 77/170 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs748705352; called by muse, mutect2, varscan2
- ATXN2L | c.1903C>T p.P635S | Missense Mutation (SNP) | VAF 118/262 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- BCORL1 | c.4797_4798insGGGAAGAA p.L1600Gfs*33 | Frame Shift Ins (INS) | VAF 107/127 reads (84%) | called by mutect2, pindel, varscan2
- CBL | c.418del p.M140Cfs*12 | Frame Shift Del (DEL) | VAF 87/214 reads (41%) | called by mutect2, pindel, varscan2
- COL15A1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 128/388 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- EDRF1 | c.3065G>A p.R1022Q (on ENST00000356792 / NM_001202438.2; = p.R988Q on NM_015608.2) | Missense Mutation (SNP) | VAF 100/359 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EFCAB8 | c.2791-1G>A p.X931_splice | Splice Site (SNP) | VAF 64/155 reads (41%) | called by muse, mutect2, varscan2
- FAM209A | c.262C>A p.P88T | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GRIN2B | c.295T>C p.F99L | Missense Mutation (SNP) | VAF 118/282 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- HRNR | c.7141G>A p.E2381K | Missense Mutation (SNP) | VAF 154/2612 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2
- LRP1 | c.10507G>A p.D3503N | Missense Mutation (SNP) | VAF 94/239 reads (39%) | SIFT tolerated (1); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- METTL24 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 92/323 reads (28%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- METTL24 | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 90/319 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- OBSCN | c.21539G>A p.G7180D | Missense Mutation (SNP) | VAF 364/544 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- OR1J4 | c.928G>A p.V310I | Missense Mutation (SNP) | VAF 56/238 reads (24%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHGB2 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 38/287 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RBL1 | c.716T>C p.F239S | Missense Mutation (SNP) | VAF 84/192 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AK8 | c.936G>A p.T312= | Silent (SNP) | VAF 83/302 reads (27%) | catalogued as rs776890411; called by muse, mutect2, varscan2
- ALDH16A1 | c.660C>T p.F220= | Silent (SNP) | VAF 147/331 reads (44%) | called by muse, mutect2, varscan2
- ARL16 | c.531T>G p.R177= | Silent (SNP) | VAF 133/276 reads (48%) | called by muse, mutect2, varscan2
- CHAT | c.1173C>T p.D391= | Silent (SNP) | VAF 117/433 reads (27%) | catalogued as rs141690626; called by muse, varscan2
- GPR158 | c.2328C>T p.G776= | Silent (SNP) | VAF 52/588 reads (9%) | catalogued as rs746374308, COSV66268767; called by muse, mutect2
- JAG2 | c.3702C>T p.Y1234= | Silent (SNP) | VAF 95/181 reads (52%) | catalogued as rs776629011; called by muse, mutect2, varscan2
- KCNB1 | c.1659G>A p.Q553= | Silent (SNP) | VAF 93/320 reads (29%) | catalogued as COSV65566286; called by muse, mutect2, varscan2
- KIAA1217 | c.1200C>T p.H400= | Silent (SNP) | VAF 125/391 reads (32%) | catalogued as rs374824948; called by muse, mutect2, varscan2
- KLHDC10 | c.66C>T p.G22= | Silent (SNP) | VAF 107/265 reads (40%) | catalogued as rs1294218920; called by muse, mutect2, varscan2
- LILRA5 | c.417C>T p.Y139= | Silent (SNP) | VAF 121/246 reads (49%) | called by muse, mutect2, varscan2
- LRP1 | c.10506G>A p.K3502= | Silent (SNP) | VAF 93/238 reads (39%) | catalogued as rs1422191819; called by muse, mutect2, varscan2
- LRRIQ4 | c.1104C>T p.V368= | Silent (SNP) | VAF 91/187 reads (49%) | called by muse, mutect2, varscan2
- MAGI2 | c.2973C>T p.I991= | Silent (SNP) | VAF 95/207 reads (46%) | catalogued as rs755558071, COSV62639778; called by muse, mutect2, varscan2
- MMP13 | c.663G>A p.A221= | Silent (SNP) | VAF 7/181 reads (4%) | catalogued as rs143331971; ClinVar: uncertain significance; called by muse, mutect2
- PCDHB16 | c.1767G>A p.V589= | Silent (SNP) | VAF 258/571 reads (45%) | catalogued as rs17844660; called by muse, mutect2, varscan2
- PKDCC | c.1302C>T p.L434= | Silent (SNP) | VAF 109/244 reads (45%) | catalogued as rs1477091490, COSV54307517; called by muse, mutect2, varscan2
- PPP6C | c.855C>T p.F285= | Silent (SNP) | VAF 121/379 reads (32%) | called by muse, mutect2, varscan2
- RACK1 | c.175C>T p.L59= | Silent (SNP) | VAF 126/272 reads (46%) | called by muse, mutect2, varscan2
- RTN1 | c.945C>T p.V315= | Silent (SNP) | VAF 101/232 reads (44%) | catalogued as COSV99956561; called by muse, mutect2, varscan2
- SYNE1 | c.14994T>C p.Y4998= (on ENST00000367255 / NM_182961.4; = p.Y4927= on NM_033071.3) | Silent (SNP) | VAF 126/253 reads (50%) | called by muse, mutect2
- TAT | c.925C>T p.L309= | Silent (SNP) | VAF 78/152 reads (51%) | called by muse, mutect2, varscan2
- TPR | c.385A>C p.R129= | Silent (SNP) | VAF 65/246 reads (26%) | called by muse, mutect2, varscan2
- UNC5B | c.168C>T p.D56= | Silent (SNP) | VAF 111/373 reads (30%) | catalogued as rs548917071; called by muse, mutect2, varscan2
- VSTM2A | c.*109A>C | 3'UTR (SNP) | VAF 95/219 reads (43%) | called by muse, mutect2, varscan2
